Somatic mutation profile of tumor specimen TCGA-DY-A1DF-01A (aliquot TCGA-DY-A1DF-01A-11D-A152-10) from TCGA case TCGA-DY-A1DF, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 73.3 years (26,763 days).
Specimen TCGA-DY-A1DF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6791491b-6a8a-4227-8d1d-a2d6c14d1828.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DY-A1DF-10A (Blood Derived Normal), aliquot TCGA-DY-A1DF-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82115b75-e206-4d66-9bb3-efcf2e49c432

The open-access MAF lists 144 somatic variants for this specimen: 109 protein-altering or splice-affecting, 32 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 32, Nonsense Mutation 6, Splice Site 3, Frame Shift Ins 2, Intron 2, In Frame Ins 1, Frame Shift Del 1, 3'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 51/125 reads (41%) | catalogued as rs137852216, CM090021, COSV57654256, COSV57668550; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 97/105 reads (92%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 55/64 reads (86%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 28/29 reads (97%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.4198+1G>A p.X1400_splice | Splice Site (SNP) | VAF 22/23 reads (96%) | catalogued as COSV56852554; called by muse, mutect2, varscan2
- ACAP1 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs374334594; called by muse, mutect2, varscan2
- ADAM23 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs749823308, COSV52219251; called by muse, mutect2, varscan2
- ADAMTS1 | c.1954G>A p.V652I | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.337); catalogued as rs201769018, COSV53169152; called by muse, mutect2, varscan2
- ADGRL3 | c.687C>A p.D229E (on ENST00000506720 / NM_001322402.2; = p.D161E on NM_015236.6) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72269186; called by muse, mutect2, varscan2
- ADRA1A | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs767695098, COSV52356985; called by muse, varscan2
- AHCYL1 | c.7A>C p.M3L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs538673946, COSV100874700; called by muse, mutect2
- AKR1B1 | c.927T>G p.D309E | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV53647731; called by muse, mutect2, varscan2
- AMPH | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348357360, COSV57737817; called by muse, mutect2, varscan2
- AMY2A | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 120/449 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV101340670; called by muse, mutect2, varscan2
- APC | c.1748C>A p.S583* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as CD106404, CM058092, COSV57355587, COSV57358531; called by muse, mutect2, varscan2
- ATP11C | c.3398A>T p.*1133Lext*22 | Nonstop Mutation (SNP) | VAF 44/95 reads (46%) | catalogued as COSV59567247; called by muse, mutect2, varscan2
- CACNA1E | c.6055C>T p.R2019C (on ENST00000367573 / NM_001205293.3; = p.R1976C on NM_000721.4) | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1259782913, COSV62388920; called by muse, mutect2, varscan2
- CACNG3 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 74/125 reads (59%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.782); catalogued as rs140935639, COSV99135321; called by muse, mutect2, varscan2
- CAPN2 | c.1125G>T p.R375S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54337149; called by muse, mutect2, varscan2
- CD36 | c.988A>G p.I330V | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.914); catalogued as COSV99987820; called by muse, mutect2
- CDH13 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs773529566, COSV51815551; called by muse, mutect2, varscan2
- CFHR3 | c.590G>C p.W197S | Missense Mutation (SNP) | VAF 243/536 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66402525; called by muse, mutect2, varscan2
- CFHR5 | c.147A>C p.E49D | Missense Mutation (SNP) | VAF 72/352 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as COSV56823507, COSV56823864; called by muse, mutect2, varscan2
- CNTNAP5 | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs374739161; called by muse, mutect2, varscan2
- COL11A1 | c.3604C>A p.L1202M | Missense Mutation (SNP) | VAF 90/205 reads (44%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.994); catalogued as COSV62175711, COSV62176104, COSV62187276; called by muse, mutect2, varscan2
- COL12A1 | c.6732G>T p.R2244S | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.114); catalogued as COSV59398889; called by muse, mutect2, varscan2
- CP | c.1588G>T p.A530S | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52831516; called by muse, mutect2, varscan2
- CST6 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 28/29 reads (97%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs1474618215, COSV56411554, COSV56411925; called by muse, mutect2, varscan2
- CTTNBP2 | c.3701C>T p.S1234F | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV50413755; called by muse, mutect2, varscan2
- DCX | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV57571227; called by muse, mutect2, varscan2
- DIPK2B | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs1253132192, COSV65005510; called by muse, mutect2, varscan2
- DNAI1 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.737); catalogued as COSV54282094; called by muse, mutect2, varscan2
- DRAXIN | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs533314493, COSV53842276; called by muse, mutect2, varscan2
- EGFR | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs559717059, CM164464, COSV51776282; called by muse, mutect2, varscan2
- EPB41L3 | c.3112C>T p.R1038* | Nonsense Mutation (SNP) | VAF 59/66 reads (89%) | catalogued as COSV59443182; called by muse, mutect2, varscan2
- EPC2 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99310109; called by muse, mutect2, varscan2
- ESYT3 | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 41/122 reads (34%) | catalogued as rs184387509, COSV67441268; called by muse, mutect2, varscan2
- FOLH1 | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 63/75 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV57051204; called by muse, mutect2, varscan2
- FRG1 | c.685A>G p.K229E | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.031); catalogued as COSV57003518; called by muse, mutect2, varscan2
- GLI2 | c.1541A>C p.K514T (on ENST00000361492 / NM_001374353.1; = p.K531T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58044857; called by muse, mutect2, varscan2
- GNAZ | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV50737503; called by muse, mutect2, varscan2
- GRID1 | c.1433T>A p.L478Q | Missense Mutation (SNP) | VAF 46/50 reads (92%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as COSV60035061, COSV60049941; called by muse, mutect2, varscan2
- GYG2 | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58550571; called by muse, mutect2, varscan2
- H2AZ1 | c.127A>T p.S43C | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV56455490; called by muse, mutect2, varscan2
- HAVCR2 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV57153468; called by muse, mutect2, varscan2
- HSPA4L | c.276G>T p.Q92H | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV56546388; called by muse, mutect2, varscan2
- HUWE1 | c.4421C>G p.A1474G | Missense Mutation (SNP) | VAF 80/168 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.258); catalogued as COSV53351462; called by muse, mutect2, varscan2
- IFT122 | c.693G>T p.E231D (on ENST00000348417 / NM_052989.3; = p.E282D on NM_052985.4) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.931); catalogued as COSV56204556; called by muse, mutect2, varscan2
- IK | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs758451409, COSV70257918; called by muse, mutect2, varscan2
- INHBA | c.764T>G p.V255G | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV99638274; called by muse, mutect2
- KCNB2 | c.895G>A p.V299M | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV73051008; called by muse, mutect2, varscan2
- KCNH5 | c.1273T>G p.F425V | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59764388; called by muse, mutect2, varscan2
- KIF20B | c.2605C>G p.P869A (on ENST00000371728 / NM_001284259.2; = p.P829A on NM_016195.4) | Missense Mutation (SNP) | VAF 81/92 reads (88%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1457068575, COSV53309652; called by muse, mutect2, varscan2
- KMT2C | c.1245_1246insG p.F416Vfs*31 | Frame Shift Ins (INS) | VAF 96/366 reads (26%) | catalogued as COSV100075890; called by mutect2, pindel, varscan2
- KRTAP13-2 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs755365119, COSV67761889, COSV67761896; called by muse, mutect2, varscan2
- KRTAP20-2 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 104/306 reads (34%) | PolyPhen benign (0.003); catalogued as rs1426063734, COSV58183402; called by muse, varscan2
- LILRB1 | c.1296G>T p.R432S (on ENST00000427581; = p.R396S on NM_006669.6) | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV61119223; called by muse, mutect2, varscan2
- MAGEA10 | c.1002G>C p.L334F | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as rs745481385, COSV54884604; called by muse, mutect2, varscan2
- MAP3K15 | c.3856C>T p.R1286W | Missense Mutation (SNP) | VAF 79/178 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748198804, COSV58832622; called by muse, mutect2, varscan2
- MMP16 | c.1712G>A p.C571Y | Missense Mutation (SNP) | VAF 112/214 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54171958; called by muse, mutect2, varscan2
- MROH5 | c.289A>G p.M97V | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs745771461, COSV101436114; called by muse, mutect2, varscan2
- MS4A2 | c.364A>T p.N122Y | Missense Mutation (SNP) | VAF 86/93 reads (92%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.678); catalogued as COSV54012856; called by muse, mutect2, varscan2
- MYBL1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1367098628, COSV72919044; called by muse, mutect2, varscan2
- NBN | c.979G>T p.G327C | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV55374149; called by muse, mutect2, varscan2
- NEB | c.9176A>G p.K3059R | Missense Mutation (SNP) | VAF 89/143 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1336510691, COSV51428500, COSV99424190; called by muse, mutect2, varscan2
- NEXMIF | c.632A>C p.K211T | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50022316; called by muse, mutect2, varscan2
- NKAP | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.749); catalogued as rs1264489828, COSV101004280; called by muse, mutect2, varscan2
- OR2L8 | c.887T>A p.V296E | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61727193; called by muse, mutect2, varscan2
- PAK3 | c.1676G>A p.R559H (on ENST00000262836 / NM_001324328.2; = p.R544H on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/176 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as rs1251435916, COSV53276325, COSV99457053; called by muse, mutect2, varscan2
- PAPOLB | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 48/386 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); catalogued as COSV68201845; called by muse, mutect2, varscan2
- PAPPA2 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs555801320, COSV62772143; called by muse, mutect2, varscan2
- PCDHGB6 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.668); catalogued as rs1469424988, COSV53972035; called by muse, mutect2, varscan2
- PER1 | c.45G>T p.R15S | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); catalogued as COSV57920424; called by muse, mutect2, varscan2
- PI4KA | c.2593C>T p.R865C | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55411732; called by muse, mutect2, varscan2
- PIK3CB | c.137T>A p.V46E | Missense Mutation (SNP) | VAF 120/185 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56687321; called by muse, mutect2, varscan2
- PITRM1 | c.471G>C p.Q157H | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as COSV56533671; called by muse, mutect2, varscan2
- PLEKHG2 | c.1354C>T p.R452* | Nonsense Mutation (SNP) | VAF 19/21 reads (90%) | catalogued as rs770390692, COSV52681800; called by muse, mutect2, varscan2
- PNO1 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV54561900; called by muse, mutect2, varscan2
- PPFIA2 | c.1518G>C p.K506N | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61038222; called by muse, mutect2, varscan2
- QRFPR | c.932A>C p.K311T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV57678039; called by muse, mutect2, varscan2
- RABL3 | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as COSV56336618; called by muse, mutect2, varscan2
- RBP2 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs117646086, COSV51674112; called by muse, mutect2, varscan2
- RGN | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.366); catalogued as rs138412897, COSV60276421; called by muse, mutect2, varscan2
- RPTOR | c.1685G>T p.C562F | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60810894, COSV60819929; called by muse, mutect2, varscan2
- SBF2 | c.1827C>G p.D609E | Missense Mutation (SNP) | VAF 32/34 reads (94%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.874); catalogued as COSV56302504; called by muse, mutect2, varscan2
- SCNN1D | c.1751T>C p.I584T (on ENST00000338555; = p.I748T on NM_001130413.4) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100330245; called by muse, mutect2, varscan2
- SEC14L5 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs774706819, COSV52039395; called by muse, mutect2, varscan2
- SEMA4F | c.551-1G>T p.X184_splice | Splice Site (SNP) | VAF 12/49 reads (24%) | catalogued as COSV60283870; called by muse, mutect2, varscan2
- SERPINA4 | c.1064A>C p.Q355P | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV54070495; called by muse, mutect2, varscan2
- SLC13A3 | c.888G>C p.W296C | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51718011, COSV99287305, COSV99287552; called by muse, mutect2, varscan2
- SLC25A53 | c.598C>A p.Q200K | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV62459306, COSV62460664; called by muse, mutect2, varscan2
- SLC26A2 | c.1607G>T p.C536F | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99640364; called by muse, mutect2, varscan2
- SLC45A1 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.081); catalogued as rs749157979, COSV57096638; called by muse, mutect2, varscan2
- SLIT1 | c.3173C>T p.A1058V | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs371409196; called by muse, mutect2, varscan2
- SMYD1 | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV101352505; called by muse, mutect2, varscan2
- SYNE1 | c.24190C>T p.R8064C (on ENST00000367255 / NM_182961.4; = p.R7993C on NM_033071.3) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753271124, COSV99576171; called by muse, mutect2, varscan2
- SYNE1 | c.7001A>G p.E2334G (on ENST00000367255 / NM_182961.4; = p.E2341G on NM_033071.3) | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs760292883, COSV99576179; called by muse, mutect2, varscan2
- TLX2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1486412313, COSV52046359; called by muse, mutect2, varscan2
- TNFAIP6 | c.773A>C p.N258T | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.971); catalogued as COSV54641418; called by muse, mutect2, varscan2
- TRPV6 | c.484C>G p.H162D | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63892252; called by muse, mutect2, varscan2
- TTN | c.53020G>T p.E17674* (on ENST00000591111; = p.E10250* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 12/119 reads (10%) | catalogued as COSV60149690; called by muse, mutect2
- TTN | c.36774A>C p.K12258N (on ENST00000591111; = p.K4834N on NM_003319.4) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | PolyPhen possibly damaging (0.642); catalogued as COSV59899538, COSV60149716; called by muse, mutect2
- UNC13C | c.799G>C p.V267L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.982); catalogued as COSV52888489; called by muse, mutect2, varscan2
- XPO4 | c.3397T>C p.F1133L | Missense Mutation (SNP) | VAF 240/432 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55009167; called by muse, mutect2, varscan2
- ZNF169 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated (0.5); PolyPhen benign (0.157); catalogued as COSV100566356; called by muse, mutect2, varscan2
- APC | c.4643del p.N1548Tfs*17 | Frame Shift Del (DEL) | VAF 69/143 reads (48%) | called by mutect2, pindel, varscan2
- ARID1A | c.2402dup p.Q802Sfs*15 | Frame Shift Ins (INS) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- CELA2A | c.227+3_227+6dup p.X76_splice | Splice Site (INS) | VAF 41/88 reads (47%) | called by mutect2, pindel, varscan2
- TRIM54 | c.837_842dup p.L280_Q281insHL (on ENST00000380075 / NM_187841.3; = p.L322_Q323insHL on NM_032546.4) | In Frame Ins (INS) | VAF 15/63 reads (24%) | called by mutect2, varscan2
- ASIC4 | c.738G>A p.S246= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs1034380385, COSV61731433; called by muse, mutect2, varscan2
- ATP10A | c.3000C>T p.S1000= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs765201119, COSV63514921; ClinVar: likely benign; called by muse, mutect2, varscan2
- BICC1 | c.2286T>G p.G762= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs750739283, COSV99570844; called by muse, mutect2, varscan2
- CACNA2D3 | c.993C>T p.F331= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as rs375011891; called by muse, mutect2, varscan2
- CNGA4 | c.1552C>T p.L518= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV101171858, COSV66006259; called by muse, mutect2
- CSMD1 | c.2646C>T p.N882= (on ENST00000520002; = p.N881= on NM_033225.6) | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs370427726; called by muse, mutect2, varscan2
- ESPNL | c.2676C>T p.H892= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as rs557336771, COSV58035780; called by muse, mutect2, varscan2
- H2AZ1 | c.126C>A p.T42= | Silent (SNP) | VAF 27/42 reads (64%) | catalogued as COSV56455501; called by muse, mutect2, varscan2
- HMCN1 | c.4851G>A p.T1617= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs781719479, COSV54911645; called by muse, mutect2, varscan2
- IGFBP3 | c.570C>T p.Y190= | Silent (SNP) | VAF 91/268 reads (34%) | catalogued as rs766767739, COSV51872748; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1890C>T p.Y630= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as rs764610412, COSV56271758; called by muse, mutect2, varscan2
- KCNG4 | c.21C>T p.D7= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs770214632, COSV57582710; called by muse, mutect2
- KRBA1 | c.2451C>T p.L817= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs200788949; called by muse, mutect2, varscan2
- MAGEB2 | c.543C>T p.I181= | Silent (SNP) | VAF 42/75 reads (56%) | catalogued as rs140291899, COSV66781032; called by muse, mutect2, varscan2
- MRPL18 | c.306G>A p.V102= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV51706152; called by muse, mutect2, varscan2
- NCAM2 | c.1062C>T p.I354= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as rs750015611, COSV53056918, COSV53083168, COSV99524164; called by muse, mutect2, varscan2
- PCDHA11 | c.810C>T p.D270= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as rs782111162, COSV56516151; called by muse, mutect2, varscan2
- PHKB | c.1848T>C p.L616= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV54525079; called by muse, mutect2, varscan2
- PITPNM2 | c.1857C>T p.G619= | Silent (SNP) | VAF 12/15 reads (80%) | catalogued as rs773167733, COSV54902936; called by muse, mutect2, varscan2
- PKP4 | c.1008G>A p.S336= | Silent (SNP) | VAF 37/56 reads (66%) | catalogued as rs200934987, COSV67677182; called by muse, mutect2, varscan2
- PREX1 | c.4485G>A p.A1495= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs768896615, COSV64253405, COSV64254134; called by muse, mutect2
- PTPRF | c.3264G>A p.Q1088= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV63446110; called by muse, mutect2, varscan2
- RHOXF2B | c.369C>T p.G123= | Silent (SNP) | VAF 95/125 reads (76%) | catalogued as rs782456783, COSV65054822; called by muse, mutect2, varscan2
- SCML1 | c.135T>A p.S45= (on ENST00000380041 / NM_001037540.3; = p.S18= on NM_006746.6) | Silent (SNP) | VAF 59/154 reads (38%) | catalogued as COSV66240847; called by muse, mutect2, varscan2
- SLC13A4 | c.186G>A p.P62= | Silent (SNP) | VAF 75/265 reads (28%) | catalogued as rs1027260078, COSV62461533; called by muse, mutect2, varscan2
- SLC6A2 | c.291G>A p.P97= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as rs749112583, COSV54913330; called by muse, mutect2, varscan2
- SYT16 | c.757C>A p.R253= | Silent (SNP) | VAF 56/62 reads (90%) | catalogued as COSV101413429, COSV70857455; called by muse, mutect2, varscan2
- TMLHE | c.576A>G p.V192= | Silent (SNP) | VAF 63/301 reads (21%) | catalogued as COSV57687871; called by muse, mutect2, varscan2
- TNR | c.1722C>T p.V574= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs757250730, COSV54893996; called by muse, mutect2, varscan2
- TRPM3 | c.4569A>G p.K1523= (on ENST00000357533 / NM_001366142.2; = p.K1378= on NM_020952.6) | Silent (SNP) | VAF 31/144 reads (22%) | catalogued as COSV62588600; called by muse, mutect2, varscan2
- TTN | c.61194C>T p.G20398= (on ENST00000591111; = p.G12974= on NM_003319.4) | Silent (SNP) | VAF 14/158 reads (9%) | catalogued as rs369516025; called by muse, mutect2
- WASF2 | c.361T>C p.L121= | Silent (SNP) | VAF 79/208 reads (38%) | catalogued as COSV71005875; called by muse, mutect2, varscan2
- CACNB4 | c.148-90305G>A | Intron (SNP) | VAF 17/63 reads (27%) | catalogued as rs981404804, COSV52396566; called by muse, mutect2, varscan2
- CXCR3 | c.*2G>C | 3'UTR (SNP) | VAF 20/43 reads (47%) | catalogued as COSV101031723; called by muse, mutect2, varscan2
- MCRS1 | c.11-193G>A | Intron (SNP) | VAF 4/15 reads (27%) | catalogued as rs188014210, COSV59460202; called by muse, mutect2, varscan2
